Surgical pathology report (de-identified scan), TCGA case TCGA-XV-A9W2, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Capital Biosciences, specimen TCGA-XV-A9W2-01A (Primary Tumor).

Pathology Report

Date:

Patient ID:

Age:

Sex:

M

Clinical Dx:

Melanoma

Tumor Location:

Skin

Localization:

Right forearm

Source:

Epithelial melanoma

Clark Level (1-5):

2

Breslow (mm):

1

Tumor:

1

Normal:

0

Metastasis:

0

Stage (I-IV):

I

Tumor size (mm x mm):

1.5x2

NeoAdj ImmunoTx:

No

ICD-0-3

Melanoma, NOS 8720/3

Site: Forearm NOS C44.6

hw
4/8/14

orig Review 1/26/14 (New corrected report)

Dual/Synchronous Primary-Noted		☒

Source: NCI Genomic Data Commons file 6e28b2c6-ce21-47c7-acc0-3e5dbc1687d0 (TCGA-XV-A9W2.D9061311-BEFE-49D0-8240-EA7381603A8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).